Surgical pathology report (de-identified scan), TCGA case TCGA-AY-A8YK, project TCGA-COAD (Colon Adenocarcinoma), tissue source site UNC, specimen TCGA-AY-A8YK-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REVISED REPORT

ICD-3

Case Number :

Adenocarcinoma NDS 8/46/3
Site Sigmoid colon C18.7
Q10 4/13/14

Diagnosis:

A: Colon, rectosigmoid junction, resection

Tumor Histologic Type: invasive colonic adenocarcinoma (see comment)

Histologic Grade: low grade, grade 2 of 4 (moderately differentiated)

Tumor Size: 5.2 cm in diameter

Tumor Location: sigmoid colon, just proximal to rectosigmoid junction

Depth of Invasion: through muscularis propria and into pericolic soft tissues

Lymphovascular Invasion: present

Perineural Invasion: not identified

Margins:

Proximal margin: negative, 6.5 cm away

Distal margin: negative, 5.0 cm away

Mesenteric margin: negative

Regional Lymph Nodes:

Total number with metastases: 6

Total number examined: 24

Additional Pathologic Findings: none

AJCC Pathologic TNM Stage: pT3 pN2a

Note: This pathologic stage assessment is based on information available at the time of this report and is subject to change pending clinical review and additional information.

Comment:

Immunostains for mismatch repair protein expression are pending. The results will be issued as an addendum to this report.

Materials will be submitted to the for microsatellite instability testing. These results will be issued

[page 2 of 3]
in a separate Molecular Pathology report.

Clinical History:

-year-old male with a clinical diagnosis of colon cancer.

Gross Description:

Received is one appropriately labeled container, additionally labeled "rectosigmoid junction, stitch is distal" and holds a 15 cm in length x 3.5 cm in open circumference segment of large bowel oriented as stated above. The proximal mucosal margin is inked blue, the distal mucosal margin is inked black, and the tinea and surrounding yellow lobulated fat is inked green for identification purposes. Approximately 6.5 cm from the proximal mucosal margin and 5.0 cm from the distal mucosal margin, there is a 5.2 cm proximal to distal x 4.0 cm circumferential tan firm mass with central ulceration and raised edges.

The mass on section extends up to 1.2 cm through the muscularis propria into the attached yellow lobulated fat. The mass comes to within 0.8 cm from the yellow intact peritonealized surface. The mass is present at the rectosigmoid junction and is not surrounded by mesorectum. No additional abnormalities are noted. Tumor and normal are submitted to tissue procurement.

Block Summary:

- A1 - Proximal en face mucosal margin
- A2-A3 - Distal en face mucosal margin
- A4 - Mesenteric vascular pedicle margin
- A5 - Lymph node present at mesenteric vascular pedicle margin, bisected
- A6-A7 - Mass with extension into fat
- A8 - Mass with respect to tinea
- A9 - Additional section of mass with extension into fat
- A10 - One lymph node trisected
- A11 - One lymph node, trisected
- A12-A13 - Multiple lymph nodes, each cassette
- A14 - One lymph node bisected
- A15-A16 - Multiple lymph nodes each cassette
- A17-A19 - One lymph node each cassette, each sectioned

Tissue remains in formalin.

Addendum

To add the results of immunostains

Addendum Comment

Immunostains for mismatch repair protein expression are performed on

[page 3 of 3]
block A8 and show normal expression of MLH1, PMS2, MSH2, and MSH6 within the tumor. Correlate with the results of microsatellite instability testing.

Source: NCI Genomic Data Commons file 35cf474a-e50c-4507-a460-fd0002dd77a6 (TCGA-AY-A8YK.22C33C79-0791-40C1-A97C-F1C1AD76063E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).